CPTAC case C3L-08265 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/19862527-683d-4f46-83ad-b516a78b41e8

Demographics
Sex at birth: female; Race: white; Year of birth: 1960; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 61.0 years (22,274 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: N3b; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 664 days (1.8 years); Progression or recurrence: yes; Days to last follow up: 664 days (1.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 15; Lymph nodes tested: 31.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 41 days; Days to treatment end: 178 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Days to treatment start: 41 days; Days to treatment end: 178 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 41 days; Days to treatment end: 178 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 633 days (1.7 years).

Follow-up (2 entries)
- Days to follow up: 346 days; Disease response: Progressive Disease; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 664 days (1.8 years); Disease response: Progressive Disease; Karnofsky performance status: 70; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 40; Cigarettes per day: 20; Tobacco smoking onset year: 1980; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08265-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 892 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08265-23: Section location: Stomach, NOS; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3L-08265-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
